Somatic mutation profile of tumor specimen MMRF_1433_3_BM_CD138pos (aliquot MMRF_1433_3_BM_CD138pos_T1_KHS5U_L15696) from MMRF case MMRF_1433, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.8 years (20,373 days).
Specimen MMRF_1433_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0964568f-31e4-4550-8c5e-4fded0da3921.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1433_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1433_1_PB_Whole_C2_KAS5U_L01389; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57235e8d-756a-4c4a-8107-0709a4539f51

The open-access MAF lists 166 somatic variants for this specimen: 62 protein-altering or splice-affecting, 23 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, 3'UTR 44, Silent 23, Intron 18, 5'UTR 10, 3'Flank 5, Frame Shift Del 4, 5'Flank 3, Splice Site 1, Nonsense Mutation 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.779); catalogued as COSV67016767; called by muse, mutect2, varscan2
- ACAP1 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV50134614; called by muse, mutect2, varscan2
- ATM | c.8402G>A p.C2801Y | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53745608; called by muse, mutect2, varscan2
- IGLV3-9 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1187894997; called by muse, varscan2
- KLHL29 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1349173171; called by muse, mutect2, varscan2
- OBSCN | c.3814G>T p.A1272S | Missense Mutation (SNP) | VAF 153/339 reads (45%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.644); catalogued as COSV52816512; called by muse, varscan2
- PADI6 | c.1090T>C p.C364R | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770181514; called by muse, mutect2, varscan2
- PLA2G4C | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62788171; called by muse, mutect2, varscan2
- PPP1R3A | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52881558; called by muse, mutect2, varscan2
- PRKD2 | c.1903T>A p.L635M | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99354464; called by muse, mutect2, varscan2
- SEPTIN9 | c.292C>T p.P98S (on ENST00000427177 / NM_001113491.2; = p.P80S on NM_006640.4) | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs866528394, COSV61202801; called by muse, mutect2, varscan2
- SLC43A2 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100025245; called by muse, mutect2, varscan2
- SYT16 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV70859382; called by muse, mutect2, varscan2
- TRDN | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV62113491; called by muse, mutect2, varscan2
- ZER1 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1465125881; called by muse, mutect2, varscan2
- ABCC9 | c.3614A>G p.N1205S | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ADAM15 | c.143T>G p.V48G | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ADAM29 | c.2462A>T p.*821Lext*61 | Nonstop Mutation (SNP) | VAF 154/372 reads (41%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ADAMTS3 | c.1856A>C p.Q619P | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ARVCF | c.579del p.E194Sfs*128 | Frame Shift Del (DEL) | VAF 30/81 reads (37%) | called by mutect2, pindel, varscan2
- BRINP2 | c.1954T>A p.S652T | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC40 | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CELSR2 | c.7535G>C p.W2512S | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHIC2 | c.159_161del p.S54del | In Frame Del (DEL) | VAF 26/78 reads (33%) | called by pindel, varscan2
- CHMP1B | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CLVS2 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- COL20A1 | c.2910C>G p.F970L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CREBRF | c.1006A>G p.N336D | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- DIS3 | c.784A>C p.T262P | Missense Mutation (SNP) | VAF 83/112 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2
- EHBP1 | c.1147_1151delinsG p.N383Gfs*2 | Frame Shift Del (DEL) | VAF 59/155 reads (38%) | called by pindel, varscan2*
- FAM111B | c.1979A>T p.K660I | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- FAT1 | c.7145A>C p.D2382A | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FREM3 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCC2 | c.2381A>T p.N794I | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- HABP2 | c.1432A>C p.N478H | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HNRNPC | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 124/299 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- INO80D | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 71/137 reads (52%) | called by muse, mutect2, varscan2
- KRT84 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- KRT85 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MIXL1 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MN1 | c.3374G>A p.G1125D | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MSR1 | c.643T>A p.L215I | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NLGN1 | c.1762A>C p.I588L | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PEX11A | c.372_375del p.H125Tfs*8 | Frame Shift Del (DEL) | VAF 155/345 reads (45%) | called by mutect2, pindel, varscan2
- PTPN23 | c.4837G>A p.G1613R | Missense Mutation (SNP) | VAF 142/349 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PTPRK | c.3020G>C p.G1007A (on ENST00000368215 / NM_001291984.2; = p.G1008A on NM_002844.4) | Missense Mutation (SNP) | VAF 125/326 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- RICTOR | c.2350C>T p.L784F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RPL5 | c.73+5_73+24del p.X25_splice | Splice Site (DEL) | VAF 46/158 reads (29%) | called by mutect2, pindel, varscan2
- SEC62 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SKOR2 | c.1945T>C p.S649P | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- SLC12A6 | c.164G>C p.S55T | Missense Mutation (SNP) | VAF 163/375 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC4A8 | c.2453G>C p.G818A | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGFBR3 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM121 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMIGD3 | c.529G>A p.G177R (on ENST00000369717 / NM_001081976.2; = p.G258R on NM_020683.7) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAM1L1 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM47 | c.788A>C p.E263A | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TUBD1 | c.376del p.E126Kfs*14 | Frame Shift Del (DEL) | VAF 80/219 reads (37%) | called by mutect2, pindel, varscan2
- WNK3 | c.413T>G p.V138G | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF383 | c.1119G>T p.K373N | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF585B | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIRC7 | c.45G>A p.Q15= | Silent (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- CAMK2B | c.1068G>A p.T356= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs538860346; called by muse, mutect2
- CLGN | c.333G>A p.L111= | Silent (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- DHRS4 | c.33C>A p.A11= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as COSV57481734; called by muse, mutect2, varscan2
- EMB | c.117G>A p.S39= | Silent (SNP) | VAF 93/258 reads (36%) | catalogued as rs112602380, COSV57482377; called by muse, mutect2, varscan2
- IGLV3-9 | c.126G>C p.G42= | Silent (SNP) | VAF 68/178 reads (38%) | catalogued as rs568866334; called by muse, varscan2
- IL18R1 | c.732G>A p.E244= | Silent (SNP) | VAF 108/273 reads (40%) | catalogued as rs759376271; called by muse, mutect2, varscan2
- LARP4 | c.411A>G p.S137= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- LIMD2 | c.18A>C p.G6= | Silent (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- MUC17 | c.1812T>C p.S604= | Silent (SNP) | VAF 268/589 reads (46%) | catalogued as rs924264870; called by muse, mutect2, varscan2
- NECTIN3 | c.117G>A p.L39= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as rs1452881807; called by muse, mutect2, varscan2
- PIF1 | c.417G>A p.L139= | Silent (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- SLC7A9 | c.105C>T p.G35= | Silent (SNP) | VAF 72/196 reads (37%) | called by muse, mutect2, varscan2
- TBC1D10B | c.198G>C p.S66= | Silent (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- TIGD1 | c.1230C>T p.L410= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- TLR7 | c.2337T>C p.L779= | Silent (SNP) | VAF 119/136 reads (88%) | called by muse, mutect2, varscan2
- TUBGCP4 | c.1791C>G p.V597= (on ENST00000260383 / NM_001286414.3; = p.V596= on NM_014444.5) | Silent (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- USP3 | c.1428A>C p.A476= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as rs1486881516; called by muse, mutect2, varscan2
- WNK3 | c.411T>C p.A137= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- YEATS2 | c.2088A>G p.G696= | Silent (SNP) | VAF 36/114 reads (32%) | called by muse, mutect2, varscan2
- ZFP91 | c.321C>A p.G107= | Silent (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- ZNF503 | c.1923G>A p.S641= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.1284G>A p.L428= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs750087617; called by muse, mutect2, varscan2
- AC011503.1 | n.467+8549C>A | Intron (SNP) | VAF 49/129 reads (38%) | called by muse, mutect2, varscan2
- ACTG1 | c.-134G>T | 5'UTR (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- ADRA2A | c.-305A>G | 5'UTR (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- AK9 | c.*358A>G | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.*74G>A | 3'UTR (SNP) | VAF 32/70 reads (46%) | catalogued as rs751526560; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3849G>C | 3'UTR (SNP) | VAF 88/207 reads (43%) | catalogued as COSV53972583; called by muse, mutect2, varscan2
- ATP2B4 | c.*784C>T | 3'UTR (SNP) | VAF 36/119 reads (30%) | called by muse, mutect2, varscan2
- BHLHE40 | c.*1383G>A | 3'UTR (SNP) | VAF 18/45 reads (40%) | catalogued as rs751178895; called by muse, mutect2, varscan2
- BIRC3 | c.*2122C>G | 3'UTR (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- CACNG2 | c.-452C>A | 5'UTR (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- CD19 | c.1085-31T>A | Intron (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- CHRM3 | c.*212C>T | 3'UTR (SNP) | VAF 23/106 reads (22%) | catalogued as rs1269912531, COSV55093271; called by muse, mutect2, varscan2
- CPN2 | c.*124C>T | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- DIRAS2 | c.*806G>T | 3'UTR (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- DPP6 | c.-157C>G | 5'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- EML3 | c.22+188C>A | Intron (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- EPHB6 | c.1751-182_1751-133del | Intron (DEL) | VAF 6/26 reads (23%) | called by muse*, mutect2
- FBRS | chr16:30661321 T>A | 5'Flank (SNP) | VAF 45/113 reads (40%) | called by muse, mutect2, varscan2
- GAD1 | c.*737G>A | 3'UTR (SNP) | VAF 31/79 reads (39%) | catalogued as rs943528474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCNT2 | c.*433A>C | 3'UTR (SNP) | VAF 56/126 reads (44%) | catalogued as rs1202780095; called by muse, mutect2, varscan2
- GORASP2 | c.*671T>G | 3'UTR (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- GPR182 | c.*276A>C | 3'UTR (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- GPR75 | c.-218C>T | 5'UTR (SNP) | VAF 28/57 reads (49%) | catalogued as rs1317788376; called by muse, mutect2, varscan2
- H2AZ2 | chr7:44828530 T>G | 3'Flank (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- HEPACAM | c.*523C>G | 3'UTR (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2
- HNRNPU | c.634+23C>A | Intron (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- INTS3 | c.-54T>G | 5'UTR (SNP) | VAF 78/107 reads (73%) | called by muse, mutect2, varscan2
- KCNJ6 | c.26-2086A>G | Intron (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- KLHL42 | c.*2193T>G | 3'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as rs1360146092, COSV67145630; called by muse, varscan2
- LHX5 | c.*333C>G | 3'UTR (SNP) | VAF 4/45 reads (9%) | catalogued as rs1335349856; called by muse, mutect2
- LIMS2 | c.*597C>T | 3'UTR (SNP) | VAF 85/173 reads (49%) | catalogued as rs1344423313; called by muse, mutect2, varscan2
- LINS1 | c.*1400G>A | 3'UTR (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- MAGI2 | c.*2101G>A | 3'UTR (SNP) | VAF 39/84 reads (46%) | catalogued as rs1030328624; called by muse, mutect2, varscan2
- MIR4472-2 | n.10_12del | RNA (DEL) | VAF 5/53 reads (9%) | catalogued as rs780065289; called by pindel, varscan2*
- MSH6 | chr2:47807434 T>C | 3'Flank (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- MXD3 | c.177-37T>C | Intron (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- NAF1 | chr4:163126951 A>C | 3'Flank (SNP) | VAF 55/111 reads (50%) | called by muse, mutect2, varscan2
- NR2F1 | c.-310G>A | 5'UTR (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- OCLN | c.*641G>A | 3'UTR (SNP) | VAF 60/164 reads (37%) | called by muse, mutect2, varscan2
- OSBP | c.*1295C>G | 3'UTR (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- OTUD4 | c.*3681C>T | 3'UTR (SNP) | VAF 91/223 reads (41%) | called by muse, mutect2, varscan2
- PADI2 | c.*1183G>A | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- PARK7 | c.322+203G>T | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- PI4K2A | c.-27C>G | 5'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.-54+238C>G | Intron (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- PLPP5 | c.184-132C>T | Intron (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- PPARGC1B | c.*2918_*2940del | 3'UTR (DEL) | VAF 47/122 reads (39%) | called by mutect2, pindel*, varscan2*
- PPM1L | c.575-43241_575-43240del | Intron (DEL) | VAF 82/252 reads (33%) | called by mutect2, pindel, varscan2
- PRKG1 | c.*3682G>A | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- PRPS1 | c.*228G>A | 3'UTR (SNP) | VAF 44/56 reads (79%) | called by muse, mutect2, varscan2
- PSTPIP2 | c.213-65C>A | Intron (SNP) | VAF 90/141 reads (64%) | called by muse, mutect2, varscan2
- RFPL4B | c.*628T>A | 3'UTR (SNP) | VAF 65/144 reads (45%) | called by muse, mutect2, varscan2
- RFX7 | c.*2364T>C | 3'UTR (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- RNF213 | c.10304-356G>A | Intron (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- RPL24 | chr3:101686827 G>A | 5'Flank (SNP) | VAF 68/167 reads (41%) | catalogued as rs1051068409; called by muse, mutect2, varscan2
- RPL24 | chr3:101686828 C>T | 5'Flank (SNP) | VAF 67/164 reads (41%) | called by muse, mutect2, varscan2
- SEC61A1 | c.777+75C>G | Intron (SNP) | VAF 141/353 reads (40%) | called by muse, mutect2, varscan2
- SGK1 | c.*591C>T | 3'UTR (SNP) | VAF 3/44 reads (7%) | catalogued as rs919565678, COSV52810415; called by muse, mutect2
- SLC16A7 | c.*2579T>A | 3'UTR (SNP) | VAF 46/116 reads (40%) | called by muse, mutect2, varscan2
- SLC19A1 | c.*1016G>A | 3'UTR (SNP) | VAF 71/164 reads (43%) | called by muse, mutect2
- SLC45A4 | c.*3750C>G | 3'UTR (SNP) | VAF 98/208 reads (47%) | called by muse, mutect2, varscan2
- SLC6A2 | c.*1208A>G | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.*318C>T | 3'UTR (SNP) | VAF 58/125 reads (46%) | catalogued as rs926588686; called by muse, mutect2, varscan2
- SLCO5A1 | c.-160C>T | 5'UTR (SNP) | VAF 72/149 reads (48%) | called by muse, varscan2
- SNTB2 | c.*6916A>T | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- SNU13 | c.*18C>T | 3'UTR (SNP) | VAF 18/36 reads (50%) | catalogued as rs369403795; called by muse, mutect2, varscan2
- SNX13 | c.*363G>T | 3'UTR (SNP) | VAF 44/49 reads (90%) | called by muse, mutect2, varscan2
- SNX3 | c.*684T>G | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- STK25 | c.*1209C>T | 3'UTR (SNP) | VAF 94/220 reads (43%) | called by muse, mutect2, varscan2
- SZT2 | c.499-4717A>C | Intron (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- THAP1 | c.*1000T>C | 3'UTR (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- THUMPD2 | c.672+540C>T | Intron (SNP) | VAF 89/217 reads (41%) | catalogued as rs1396965157; called by muse, mutect2, varscan2
- TMEM144 | c.109+550T>C | Intron (SNP) | VAF 63/133 reads (47%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+1502G>A | Intron (SNP) | VAF 72/184 reads (39%) | called by muse, mutect2, varscan2
- TNFRSF19 | chr13:23674032 T>A | 3'Flank (SNP) | VAF 37/49 reads (76%) | called by muse, mutect2, varscan2
- VGLL3 | c.*5152T>A | 3'UTR (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- WDR33 | c.*1261T>G | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- WDR86 | c.-226G>A | 5'UTR (SNP) | VAF 47/116 reads (41%) | catalogued as rs949454830; called by muse, mutect2, varscan2
- XRN1 | c.*3680C>T | 3'UTR (SNP) | VAF 57/116 reads (49%) | called by muse, mutect2, varscan2
- ZPLD1 | chr3:102478266 T>C | 3'Flank (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- ZZZ3 | c.*323G>T | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
